Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AI, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AI-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: Right thyroid Gland and Isthmus, Stitch Superior Pole

Diagnosis

Multifocal papillary carcinoma, dominant 2.3 cm: Thyroid, right hemithyroidectomy specimen.

Synoptic Data

Procedure: Right hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
5 cm
3.2 cm
2.4 cm
Isthmus +/- pyramidal lobe:
2.3 cm
0.3 cm
0.7 cm
Specimen Weight: 16.7 g
Tumor Focality: Multifocal, ipsilateral
Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.3cm
Additional dimension: 2.0 cm
Additional dimension: 1.4 cm
Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Classical cytomorphology
Oncocytic or oxyphilic cytomorphology
Histologic Grade: Not applicable

10A-0-3

carcinoma, papillary, follicular
variant 8340/3

Site: Thyroid, NOS C 73.9

per TSS, follicular
variant = 100%

fw
10/21/11

[page 2 of 2]
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest dimension: 0.2cm
Histologic Type:	Papillary carcinoma, follicular variant Follicular architecture Classical cytomorphology Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:
J, MD

Gross Description

1. The specimen labeled with the patient's name and as "RT Thyroid Gland and Isthmus, Stitch Superior Pole" consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 16.7 g. The lobe measures 5.0 cm SI x 3.2 cm ML x 1.8 cm AP and the isthmus measures 2.0 cm SI x 0.3 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The mid to lower lobe contains a well delineated nodule that measures 2.0 cm SI x 2.3 cm ML x 1.4 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted in toto as follows:

1A-K lobe, superior to inferior [E-F; G-H; I-J section bisected]
1L isthmus

Source: NCI Genomic Data Commons file bf682da6-93a6-44b7-8e62-820ecb901f69 (TCGA-EM-A3AI.BFE17AA0-1A15-4BBE-B46B-87F4DDF40D4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).